MMRF case MMRF_2378 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/84ab30ee-2564-4623-95c5-eee659f50756

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 66 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 66.9 years (24,441 days); ISS stage: I; Days to last known disease status: 802 days (2.2 years); Days to last follow up: 802 days (2.2 years).
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 32 days.
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 25 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 44 days.
   Treatment given: Therapeutic agents: Melphalan; Regimen or line of therapy: First line of therapy; Days to treatment start: 86 days; Days to treatment end: 86 days.
   Treatment given: Treatment type: Stem Cell Transplantation, Autologous; Regimen or line of therapy: First line of therapy; Days to treatment start: 86 days; Days to treatment end: 86 days.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day 1 (ECOG 1): M Protein 3.08 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 54.6 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.1 mg/dL; Immunoglobulin G 35.4 g/L; Immunoglobulin A 0.38 g/L; Immunoglobulin M 0.25 g/L; Beta 2 Microglobulin 3.26 µg/mL; Lactate Dehydrogenase 3.28 µkat/L; Hemoglobin 7.38 mmol/L; Leukocytes 5.4 ×10⁹/L; Absolute Neutrophil 3.5 ×10⁹/L; Platelets 220 ×10⁹/L; Creatinine 67.2 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.38 mmol/L; Albumin 36 g/L; Total Protein 9.3 g/dL; Glucose 5.01 mmol/L.
- Day 81 (ECOG 0): M Protein 0.29 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.1 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.1 mg/dL; Immunoglobulin G 4.98 g/L; Immunoglobulin A 0.24 g/L; Immunoglobulin M 0.19 g/L; Beta 2 Microglobulin 2.09 µg/mL; Lactate Dehydrogenase 12 µkat/L; Hemoglobin 7.69 mmol/L; Leukocytes 7.1 ×10⁹/L; Absolute Neutrophil 4.8 ×10⁹/L; Platelets 198 ×10⁹/L; Creatinine 30.1 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.33 mmol/L; Albumin 40 g/L; Total Protein 6.4 g/dL; Glucose 5.78 mmol/L.
- Day 169 (ECOG 1): M Protein 0.94 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.44 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 3.11 mg/dL; Immunoglobulin G 16.6 g/L; Immunoglobulin A 1.28 g/L; Immunoglobulin M 0.16 g/L; Lactate Dehydrogenase 3.02 µkat/L; Hemoglobin 6.32 mmol/L; Leukocytes 7.3 ×10⁹/L; Absolute Neutrophil 5.4 ×10⁹/L; Platelets 191 ×10⁹/L; Creatinine 57.5 µmol/L; Blood Urea Nitrogen 4.28 mmol/L; Calcium 2.33 mmol/L; Albumin 35 g/L; Total Protein 6.7 g/dL; Glucose 5.17 mmol/L.
- Day 311 (ECOG 1): M Protein 0.41 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.29 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.43 mg/dL; Immunoglobulin G 11.3 g/L; Immunoglobulin A 1.05 g/L; Immunoglobulin M 0.48 g/L; Lactate Dehydrogenase 2.62 µkat/L; Hemoglobin 8.06 mmol/L; Leukocytes 6.8 ×10⁹/L; Absolute Neutrophil 5.3 ×10⁹/L; Platelets 235 ×10⁹/L; Creatinine 76.9 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.43 mmol/L; Albumin 43 g/L; Total Protein 6.9 g/dL; Glucose 5.01 mmol/L.
- Day 402 (ECOG 1): M Protein 0.18 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.17 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.02 mg/dL; Immunoglobulin G 10.1 g/L; Immunoglobulin A 0.99 g/L; Immunoglobulin M 0.49 g/L; Lactate Dehydrogenase 2.6 µkat/L; Hemoglobin 7.69 mmol/L; Leukocytes 6.8 ×10⁹/L; Absolute Neutrophil 4.6 ×10⁹/L; Platelets 198 ×10⁹/L; Creatinine 74.3 µmol/L; Blood Urea Nitrogen 6.43 mmol/L; Calcium 2.35 mmol/L; Albumin 42 g/L; Total Protein 6.3 g/dL; Glucose 4.9 mmol/L.
- Day 494 (ECOG 1): M Protein 0.18 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.905 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.739 mg/dL; Immunoglobulin G 9.23 g/L; Immunoglobulin A 0.93 g/L; Immunoglobulin M 0.48 g/L; Lactate Dehydrogenase 2.9 µkat/L; Hemoglobin 8 mmol/L; Leukocytes 7.8 ×10⁹/L; Absolute Neutrophil 5.8 ×10⁹/L; Platelets 187 ×10⁹/L; Creatinine 69.8 µmol/L; Blood Urea Nitrogen 7.14 mmol/L; Calcium 2.3 mmol/L; Albumin 43 g/L; Total Protein 6.5 g/dL; Glucose 5.28 mmol/L.
- Day 595 (ECOG 1): M Protein 0.16 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.17 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.819 mg/dL; Immunoglobulin G 8.95 g/L; Immunoglobulin A 0.98 g/L; Immunoglobulin M 0.51 g/L; Lactate Dehydrogenase 3.22 µkat/L; Hemoglobin 8.12 mmol/L; Leukocytes 6.6 ×10⁹/L; Absolute Neutrophil 4.5 ×10⁹/L; Platelets 193 ×10⁹/L; Creatinine 80.4 µmol/L; Blood Urea Nitrogen 6.07 mmol/L; Calcium 2.4 mmol/L; Albumin 42 g/L; Total Protein 6.3 g/dL; Glucose 4.18 mmol/L.
- Day 704 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.5 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.962 mg/dL; Immunoglobulin G 10.3 g/L; Immunoglobulin A 1.2 g/L; Immunoglobulin M 1.28 g/L; Lactate Dehydrogenase 3 µkat/L; Hemoglobin 7.87 mmol/L; Leukocytes 8.6 ×10⁹/L; Absolute Neutrophil 6.1 ×10⁹/L; Platelets 202 ×10⁹/L; Creatinine 73.4 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.43 mmol/L; Albumin 42 g/L; Total Protein 6.7 g/dL; Glucose 5.5 mmol/L.
- Day 802 (ECOG 1): M Protein 0.14 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.45 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.917 mg/dL; Immunoglobulin G 9.76 g/L; Immunoglobulin A 1.26 g/L; Immunoglobulin M 0.92 g/L; Lactate Dehydrogenase 2.67 µkat/L; Hemoglobin 7.94 mmol/L; Leukocytes 6.9 ×10⁹/L; Absolute Neutrophil 4.5 ×10⁹/L; Platelets 265 ×10⁹/L; Creatinine 79.6 µmol/L; Blood Urea Nitrogen 6.43 mmol/L; Calcium 2.45 mmol/L; Albumin 43 g/L; Total Protein 6.8 g/dL; Glucose 5.01 mmol/L.

Other clinical attributes
- Day 1: Weight: 93 kg; Height: 172 cm.

Family history
- Relative with cancer history: no.

Biospecimens (2 samples)
- Sample MMRF_2378_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: 1 day.
- Sample MMRF_2378_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: 1 day.
